Gene-level copy-number profile of tumor specimen HTMCP-02-06-01162-01B from CGCI case HTMCP-02-06-01162, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 68.9 years (25,164 days).
Specimen HTMCP-02-06-01162-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5f2b43b0-46da-4428-961b-01c2f83baa48.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-06-01162-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,260 have no estimate.
https://portal.gdc.cancer.gov/files/06f50683-6d98-4734-bea1-e07a830cefc3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 217; copy number 1: 2,207; copy number 2: 24,275; copy number 3: 14,628; copy number 4: 10,231; copy number 5: 3,183; copy number 6: 1,313; copy number 7: 1,584; copy number 8: 237; copy number 9: 275; copy number 10: 12; copy number 11: 34; copy number 12: 55; copy number 14: 12; copy number 16: 12; copy number 19: 6; copy number 24: 20; copy number 25: 46; copy number 26: 3; copy number 47: 13.

Homozygous deletions (total copy number 0; autosomes only): 217 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,948,372–13,836,571, 21 genes: AL162413.1, AKAP8P1, AL451129.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235.
- chr9:19,705,338–19,967,994, 6 genes (within-gene range 0–2): C11orf98P1, AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3.
- chr9:20,658,309–25,938,434, 79 genes (within-gene range 0–2) (broad region; genes not listed).
- chr9:38,147,428–39,741,193, 39 genes: U8, AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5.
- chr9:40,105,822–40,266,845, 5 genes (within-gene range 0–2): AL773545.3, CDRT15P14, AL773545.1, AL773545.2, ANKRD20A2P.
- chr9:40,233,923–40,234,029, 1 gene: RNU6-1269P.
- chr9:41,126,430–42,354,454, 32 genes (within-gene range 0–1): FOXD4L6, CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.
- chr9:67,725,690–67,726,255, 2 genes: FAM27B, AL627230.1.
- chr15:20,890,206–21,167,357, 20 genes: AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P, AC126335.1, AC126335.2, BMS1P16.
- chr15:30,143,733–30,153,409, 2 genes (within-gene range 0–3): RN7SL469P, DNM1P30.
- chr15:30,223,017–30,254,508, 2 genes: AC135731.1, RNU6-17P.
- chr15:30,355,436–30,420,429, 8 genes: Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,805 genes in 49 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–145,095,528, 56 genes, copy number 6: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F, LINC01632, FP700111.1, FP700107.1, RNA5SP59, FP700111.2, FP700111.3, SRGAP2B, AC242498.1.
- chr2:44,154,789–44,772,592, 9 genes, copy number 7: RNU6-566P, PDSS1P2, AC019129.2, PPM1B, AC013717.1, RPL12P19, SLC3A1, PREPL, CAMKMT.
- chr2:53,864,069–71,686,768, 332 genes, copy number 5–8 (broad region; genes not listed).
- chr2:84,971,093–85,668,741, 35 genes, copy number 5: KCMF1, LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB.
- chr2:111,611,639–112,029,561, 11 genes, copy number 5 (within-gene range 4–5): ANAPC1, RPL34P8, AC093166.1, CENPNP2, MIR4771-2, AC093166.2, EEF1E1P1, MERTK, RN7SL297P, RTRAFP1, SLC30A6P1.
- chr7:53,187,388–112,521,670, 1,131 genes, copy number 5–14 (broad region; genes not listed).
- chr8:46,028,804–82,961,926, 543 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:84,948,585–145,066,685, 937 genes, copy number 6–7 (broad region; genes not listed).
- chr9:12,134–110,138, 8 genes, copy number 5: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1.
- chr9:452,492–5,629,748, 85 genes, copy number 8–47 (within-gene range 4–47) (broad region; genes not listed).
- chr9:26,642,697–27,297,150, 17 genes, copy number 5–9: AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN.
- chr9:27,948,078–29,826,711, 10 genes, copy number 5–9: LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr12:20,368,537–50,396,622, 552 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr12:53,935,328–54,648,493, 58 genes, copy number 5: HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3, HOXC10, AC012531.3, HOXC6, MIR196A2, HOXC-AS2, HOXC9, HOXC-AS1, HOXC8, HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD.
- chr12:92,770,637–93,019,820, 5 genes, copy number 5 (within-gene range 4–5): EEA1, AC026111.1, HNRNPA1P50, RNU6-1329P, LINC02413.
- chr12:111,443,485–111,600,256, 4 genes, copy number 5 (within-gene range 4–5): ATXN2, U7, IFITM3P5, ATXN2-AS.
- chr14:18,333,726–19,691,194, 63 genes, copy number 5 (broad region; genes not listed).
- chr14:19,975,444–34,561,298, 500 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr14:43,274,824–45,042,322, 21 genes, copy number 5 (within-gene range 3–5): TUBBP3, HNRNPUP1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28.
- chr14:49,782,083–61,083,733, 245 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:20,545,576–20,866,314, 20 genes, copy number 7–8: AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P, AC023310.2, IGHV1OR15-6, AC023310.4, NBEAP1, AC131280.1, AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3, AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P.
- chr15:22,360,639–25,000,276, 60 genes, copy number 6–10 (within-gene range 3–10): AC100757.2, AC100757.1, SPATA31E3P, GOLGA8EP, RN7SL545P, AC100757.3, GOLGA6L22, HERC2P7, HERC2P2, GOLGA8IP, RN7SL495P, WHAMMP3, AC138649.2, AC138649.5, AC138649.4, PDCD6IPP1, AC138649.3, AC138649.1, AC011767.1, NIPA1, NIPA2, CYFIP1, TUBGCP5, ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, HERC2P6, GOLGA6L2, MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P, PWRN4, PWRN1, PWRN2, AC087463.1, AC087463.2, AC090983.2, NPAP1, SNRPN, AC090983.1, RPL5P1, AC090602.1, SNURF, AC124312.1.
- chr15:24,981,994–25,042,040, 6 genes, copy number 7 (within-gene range 3–7): SNORD107, PWAR5, SNORD64, SNORD108, AC124312.2, SNORD109A.
- chr15:25,677,271–26,053,123, 6 genes, copy number 7 (within-gene range 2–7): ATP10A, RNA5SP390, MIR4715, AC016266.1, LINC02346, AC044913.2.
- chr15:26,115,726–27,541,984, 17 genes, copy number 5 (within-gene range 1–5): LINC00929, LINC02248, AC009878.2, GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5, TVP23BP1, GABRG3, GABRG3-AS1, AC136896.1, RNA5SP391, SERPINE4P, AC144833.1, AC104002.1, AC104002.2.
- chr15:50,354,959–50,686,797, 11 genes, copy number 5 (within-gene range 4–5): GABPB1-AS1, AC022087.1, MIR4712, AHCYP7, USP8, RNA5SP395, AC012170.1, USP50, TRPM7, AC084756.1, AC084756.2.
- chr15:66,582,190–68,432,163, 33 genes, copy number 5: LINC01169, SMAD6, AC013564.1, AC110048.1, AC110048.2, AC093334.1, LINC02206, AC087482.1, HMGN2P47, SMAD3, AC012568.1, AAGAB, RPS24P16, IQCH, IQCH-AS1, C15orf61, AC016355.1, MAP2K5, HNRNPA1P5, SKOR1, AC009292.2, AC009292.1, RNU6-1, AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6, HMGN2P40, AC107871.2, FEM1B, ITGA11.
- chr15:75,225,784–80,138,393, 161 genes, copy number 5–7 (broad region; genes not listed).
- chr15:95,186,634–95,327,129, 4 genes, copy number 5: LINC01197, AC104260.1, AC104260.2, AC104260.3.
- chr15:95,990,582–96,496,462, 22 genes, copy number 5: AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157, AC016251.1, NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5, AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP.
- chr17:21,614,487–32,906,584, 336 genes, copy number 5–9 (broad region; genes not listed).
- chr17:34,255,218–42,648,738, 424 genes, copy number 5–25 (broad region; genes not listed).
- chr17:55,882,301–56,595,611, 5 genes, copy number 5 (within-gene range 2–5): ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG.
- chr17:59,859,479–60,030,746, 12 genes, copy number 5: TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.4, AC005702.3.
- chr17:63,193,930–63,843,065, 29 genes, copy number 5: AC015923.1, AC005828.2, AC005828.7, AC005828.1, AC005828.3, AC005828.6, AC005828.4, CYB561, AC005828.5, PPIAP55, ACE, AC113554.1, ACE3P, KCNH6, DCAF7, RNU6-288P, TACO1, AC046185.2, MAP3K3, EEF1DP7, STRADA, LIMD2, AC046185.3, AC046185.1, CCDC47, DDX42, FTSJ3, PSMC5, SMARCD2.
- chr17:77,877,330–78,108,835, 6 genes, copy number 5 (within-gene range 4–5): LINC01973, RNU1-80P, TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P.
- chr18:15,159,724–15,330,282, 6 genes, copy number 5: AP005901.2, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr20:87,250–1,557,705, 46 genes, copy number 5 (within-gene range 3–5): DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2, AL049634.1, RNU6-917P, SIRPD.
- chr20:30,214,765–64,327,972, 870 genes, copy number 5 (broad region; genes not listed).
- chr21:20,355,748–28,137,611, 94 genes, copy number 6–26 (within-gene range 2–26) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
